Gene-level copy-number profile of tumor specimen TCGA-BR-6709-01A from TCGA case TCGA-BR-6709, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 57.3 years (20,935 days).
Specimen TCGA-BR-6709-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.66fbe896-770e-4528-8e21-bfa50b25702a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-6709-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e32853e-a366-43d4-8240-f9de5d09c668

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 172; copy number 1: 14,143; copy number 2: 41,369; copy number 3: 1,410; copy number 4: 2,186; copy number 5: 21; copy number 6: 127; copy number 7: 21; copy number 8: 7; copy number 9: 28; copy number 10: 10; copy number 11: 12; copy number 12: 20; copy number 15: 38; copy number 16: 3; copy number 20: 150; copy number 23: 13; copy number 27: 18; copy number 34: 1; copy number 38: 13; copy number 39: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-6709-01A-11D-1881-01): tumor purity 0.32, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 172 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,936,079–9,091,245, 2 genes: AL596451.1, RPS26P3.
- chr9:11,618,530–12,300,451, 4 genes (within-gene range 0–4): AL353595.1, AL589678.1, JKAMPP1, RNU2-47P.
- chr9:16,203,935–16,870,843, 6 genes: C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–5): AL359922.1.
- chr9:21,929,457–26,947,242, 43 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA.
- chr9:26,955,780–27,005,672, 2 genes (within-gene range 0–1): IFT74-AS1, LRRC19.
- chr9:29,214,322–32,727,522, 33 genes: AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1.
- chr9:36,572,862–37,034,268, 8 genes (within-gene range 0–9): MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476.
- chr14:22,086,407–22,518,871, 73 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 533 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,638,405–86,074,429, 7 genes, copy number 8 (within-gene range 3–8): LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2.
- chr3:86,235,321–86,362,474, 3 genes, copy number 6: RNU6-1129P, AC108733.1, RN7SKP284.
- chr3:86,816,740–87,993,787, 14 genes, copy number 12: AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P.
- chr8:36,277,763–37,909,037, 36 genes, copy number 6–11: MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P.
- chr8:41,609,692–42,051,994, 10 genes, copy number 6 (within-gene range 1–6): AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A.
- chr9:17,906,563–18,910,950, 1 gene, copy number 6 (within-gene range 3–6): ADAMTSL1.
- chr9:18,573,306–18,718,526, 3 genes, copy number 6: MIR3152, RN7SKP258, RAP1BP1.
- chr9:20,331,446–20,332,277, 1 gene, copy number 10: AL512635.1.
- chr9:20,411,148–20,418,427, 2 genes, copy number 10: MIR4473, RNU4-26P.
- chr9:21,367,424–21,937,651, 18 genes, copy number 5 (within-gene range 0–5): IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP.
- chr9:21,811,621–21,893,857, 3 genes, copy number 5: TUBB8P1, AL359922.2, AL359922.3.
- chr9:35,681,992–36,487,548, 38 genes, copy number 6–12 (within-gene range 0–12): TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38.
- chr9:37,002,697–37,592,604, 22 genes, copy number 9: AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P, LINC01627, GRHPR, CHCHD4P3, ZBTB5, KCTD9P3, POLR1E, AL158156.1, AL513165.1, FBXO10, AL513165.2, TOMM5.
- chr9:37,636,688–37,637,293, 1 gene, copy number 9: RAB1C.
- chr9:37,661,747–37,662,049, 1 gene, copy number 9: RN7SKP171.
- chr11:70,056,230–70,436,584, 17 genes, copy number 7: LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,647,562, 4 genes, copy number 7: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.
- chr12:66,767–3,593,973, 90 genes, copy number 15–27 (broad region; genes not listed).
- chr12:3,610,307–3,612,003, 1 gene, copy number 27: AC005831.1.
- chr12:22,573,425–27,695,564, 84 genes, copy number 15–39 (within-gene range 1–39) (broad region; genes not listed).
- chr12:28,133,249–28,581,511, 1 gene, copy number 16 (within-gene range 1–16): CCDC91.
- chr12:28,505,394–34,249,958, 122 genes, copy number 9–38 (broad region; genes not listed).
- chr16:53,701,692–56,425,545, 54 genes, copy number 6 (within-gene range 2–6): FTO, AC007496.2, AC007496.3, AC007496.1, AC007347.1, AC007347.2, AC007907.1, LINC02169, IRX3, AC018553.2, AC018553.1, LINC02140, AC018553.3, AC007343.1, LINC02183, AC007491.1, CRNDE, AC106742.1, IRX5, AC106738.1, AC106738.2, MTND5P34, AC109136.1, AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1, AC007336.3, LPCAT2, AC007336.1, CAPNS2, SLC6A2, AC136621.1, CES1P2, CES1P1, CES1, CES5A, AC040168.1, AC040168.2, AC007495.1, GNAO1, DKFZP434H168, MIR3935, AC009102.4, AC009102.1, AC009102.3, AC009102.2, AMFR, AC092140.1.

Autosomal genes at a single copy (total copy number 1): 14,143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
